TCGA case TCGA-V4-A9F5 — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bbf07e1f-8c17-4c2e-89ed-38332d82e455

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 85 years; Year of birth: 1927; Vital status: Dead; Days to death: 203 days; Year of death: 2013.

Diagnoses (2)
1. Mixed epithelioid and spindle cell melanoma (the primary disease): ICD-O-3 morphology code: 8770/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 85.7 years (31,314 days); Year of diagnosis: 2013; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T4e; AJCC clinical N: N0; AJCC clinical M: M1b; AJCC clinical stage: Stage IV; AJCC pathologic T: T4e; AJCC pathologic N: N0; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Distant Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 203 days; Sites of involvement: Eye, Choroid / Eye, Ciliary Body / Liver / Skin.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 22.
   Pathology details: Consistent pathology review: Yes; Epithelioid cell percent range: 61-90%; Extraocular nodule size: >5mm; Extrascleral extension present: Yes; Measurement type: Echographic; Spindle cell percent range: 1-30%; Tumor depth measurement: 10.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -22 days; Residual disease: R1; Treatment anatomic sites: Eye.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Mixed epithelioid and spindle cell melanoma), site: Liver. Age at diagnosis: 85.9 years (31,392 days); Days to diagnosis: 78 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Day 78 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 78 days.
- Days to follow up: 202 days; Disease response: With Tumor.
- Days to follow up: 203 days; Disease response: With Tumor.

Molecular and laboratory tests
- Test (Cytogenetics, NOS): Positive.
- Test (Cytogenetics, NOS): Positive; Chromosome arm: q.
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 40.

Other clinical attributes
- Eye color: Blue.
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 150 cm; BMI: 32.
- Comorbidities: Vascular Disease.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V4-A9F5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 70 mg.
  Slide TCGA-V4-A9F5-01A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 96; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-V4-A9F5-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9F5-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology, Tumor tissue site list: Submitted tumor site: Ciliary body.
- Primary pathology, Tumor morphology list, Tumor morphology 1: Histologic diagnosis: Epithelioid Cell.
- Primary pathology, Tumor morphology list, Tumor morphology 2: Histologic diagnosis: Spindle Cell; Tumor morphology percentage: 1-30%.
- Primary pathology, Cytogenetic abnormality list: Cytogenetic abnormality type: Chromosome 3 loss; Cytogenetic abnormality type: Chromosome 8q gain.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness measurement: Echographic Measurement.
- Primary pathology, Metastatic site list: Metastasis site: Cutaneous.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 203 days; disease-specific survival: no event (censored), 203 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 78 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9F5-01A-11D-A39V-01): tumor purity 1, ploidy 1.91, whole-genome doublings 0.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- abnormality: Loss 3; Gain 8q
- comorbidity: arteriopathy
- days to metastasis: 78
- days to outcome: 141
- days to procedure 1: -22
- diagnosis: melanoma
- disease status at death: Evidence of Disease
- line of therapy 1: first
- m stage: M0
- morphologic subtype: epithelioid
- n stage: N0
- resection status 1: R1
- smoking status: non-smoker
- staging system: AJCC
- t stage: T4e
- test methodology: aCGH
- test result: high risk
- unresectable 1: no
